Gene-level copy-number profile of tumor specimen TCGA-EA-A3Y4-01A from TCGA case TCGA-EA-A3Y4, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 40.3 years (14,706 days).
Specimen TCGA-EA-A3Y4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.e4e986e8-08be-4101-a09b-141f26b84d27.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EA-A3Y4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b751421c-895f-4ffc-90f8-d78e029565a3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,641; copy number 2: 53,246; copy number 3: 2,837; copy number 4: 381; copy number 6: 710.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EA-A3Y4-01A-51D-A242-01): tumor purity 0.57, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 710 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,620. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
